Gene-level copy-number profile of tumor specimen TCGA-85-8072-01A from TCGA case TCGA-85-8072, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.4 years (22,069 days).
Specimen TCGA-85-8072-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.7d560b44-382d-4cca-8cc3-5ff0ac469c48.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8072-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9aa56028-4a06-4c92-80bf-fe3db0d86a04

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 95; copy number 2: 10,015; copy number 3: 18,862; copy number 4: 17,504; copy number 5: 4,353; copy number 6: 3,054; copy number 7: 2,264; copy number 8: 1,745; copy number 9: 1,392; copy number 10: 196; copy number 11: 22; copy number 12: 43; copy number 15: 234; copy number 43: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8072-01A-31D-2243-01): tumor purity 0.42, ploidy 3.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,926 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–205,750,182, 1,653 genes, copy number 7–10 (broad region; genes not listed).
- chr1:206,767,602–248,919,946, 918 genes, copy number 7–8 (broad region; genes not listed).
- chr2:38,814–83,657,842, 1,389 genes, copy number 8 (broad region; genes not listed).
- chr2:172,099,438–178,830,802, 156 genes, copy number 15 (within-gene range 4–15) (broad region; genes not listed).
- chr2:179,399,728–185,505,608, 60 genes, copy number 8: RAD52P1, ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22, AC012669.1, AC009478.1, SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1, LINC01934, MIR4437, AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113, PDE1A, AC012500.1, RN7SL267P, DNAJC10, RPL31P15, Y_RNA, FRZB, RNU6-1122P, NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35, AC021851.1, AC021851.2, LIN28AP1, CACYBPP2, AC093639.3, AC093639.1, AC093639.2, AC096555.1, AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33, AC009315.1.
- chr2:188,598,791–189,877,629, 24 genes, copy number 9: AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1.
- chr2:189,917,254–189,917,758, 1 gene, copy number 9: TERF1P6.
- chr3:113,142,350–198,222,513, 1,542 genes, copy number 9–11 (broad region; genes not listed).
- chr5:44,808,947–45,895,970, 8 genes, copy number 7 (within-gene range 6–7): MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:62,547,427–63,779,336, 18 genes, copy number 7: AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 7: AL354719.1, SCAT8, GCNT1P4.
- chr11:69,072,915–69,162,440, 1 gene, copy number 43 (within-gene range 2–43): AP003071.5.
- chr11:69,147,228–73,662,819, 152 genes, copy number 8–43 (broad region; genes not listed).
- chr17:14,767,583–14,780,686, 1 gene, copy number 11: AC005863.1.

Autosomal genes at a single copy (total copy number 1): 95. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
